Surgical pathology report (de-identified scan), TCGA case TCGA-24-2260, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2260-01A (Primary Tumor).

[page 1 of 3]
Name: [REDACTED]
Address: [REDACTED]

MR No.: [REDACTED]
Service: [REDACTED]
Surgeon: [REDACTED]

Surg. Path. No.:

DOB: [REDACTED]

Sex/Race: [REDACTED]

Location: [REDACTED]

Hosp. No.: [REDACTED]

Taken/Received: [REDACTED]

TCGA-24-2260

DIAGNOSIS

OVARY, LEFT, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA,
MODERATELY-TO-POORLY DIFFERENTIATED

OVARY, RIGHT, EXCISION - PAPILLARY SEROUS ADENOCARCINOMA,
MODERATELY-TO-POORLY DIFFERENTIATED

FALLOPIAN TUBES, LEFT AND RIGHT, EXCISION - METASTATIC PAPILLARY
ADENOCARCINOMA

LARGE INTESTINE, TRANSVERSE COLON, PARTIAL EXCISION -
- METASTATIC PAPILLARY ADENOCARCINOMA (SEROSAL
AND MESENTERIC)

LARGE INTESTINE, SIGMOID COLON, EXCISION - METASTATIC PAPILLARY
ADENOCARCINOMA

LARGE INTESTINE, BIOPSIES #1 AND 2, PARTIAL EXCISIONS -
- METASTATIC PAPILLARY ADENOCARCINOMA
(INVOLVING PERICOLIC FAT ONLY)

SOFT TISSUE, OMENTUM, EXCISION - METASTATIC PAPILLARY
ADENOCARCINOMA

SPECIMEN(S) SUBMITTED

Part 1: OMENTAL CAKE
Part 2: TRANSVERSE COLON
Part 3: BOWEL BIOPSY #1
Part 4: BOWEL BIOPSY #2
Part 5: LEFT TUBE & OVARY
Part 6: RIGHT TUBE AND OVARY
Part 7: SIGMOID COLON

[page 2 of 3]
Name:

HISTORY

The patient is [REDACTED] G2, P2 with last menstrual period in [REDACTED], status post vaginal hysterectomy who now has a new pelvic mass. Clinical diagnosis: Unstated. Operative procedure: Examination under anesthesia; exploratory laparotomy; bilateral salpingo-oophorectomy.

GROSS

The specimen is received in formalin in seven containers each labelled with the patient's name. The first is labelled "#1 omental cake." It consists of an indurated, focally hemorrhagic piece of fatty tissue consistent with omentum that measures 18 x 9 x 4 cm. Transverse sections show homogenization of the fat with hemorrhage, necrosis, and formation of cysts. [REDACTED]

The second container is labelled "transverse colon." It consists of a segment of bowel measuring 14 cm in length by 3.8 cm in diameter. Both ends are stapled shut and the serosal surface in areas where it is visible is pink-tan and smooth. The mesentery is firm and appears occupied by an infiltrative process. There are hemorrhagic adhesions on the antimesenteric borders midway along the specimen. Also along the antimesenteric border is a collection of fatty tissue measuring 8.5 cm in greatest dimension that is consistent with omentum. There is a 0.3 cm mucosal erosion, but the mucosa appears otherwise tan and normally folded with no intraluminal lesions. There is no evidence of obstruction. Labelled B1, mucosa with possible erosion; B2, adhesion; B3, mesentery. [REDACTED]

The third container is labelled "#3, bowel (colon) biopsy #1." It consists of two fragments of bowel, each containing multiple staples. The fragments in aggregate measure 3 x 3 x 1.5 cm. One fragment has an adherent piece of fat consistent with an appendix epiploicus. The second fragment also has a small amount of adherent soft fatty tissue. [REDACTED]

The fourth container is labelled "#4, bowel (colon) biopsy #2." It consists of a fragment of bowel measuring 2.5 cm x 1.0 x 1.0 cm. It includes a stapled margin and a small amount of adherent fatty tissue. A second fragment of fatty tissue is present in the container measuring 1.4 cm in greatest dimension. Labelled D. [REDACTED]

The fifth [REDACTED] labelled "#5, left tube and ovary." It consists of a [REDACTED] ovary measuring 4.5 x 2.5 x 2.5

[page 3 of 3]
Name: 1

Surg. Path. No.: 1

GROSS (continued)

cm. The mesovarium is studded with a coarse papillary gray-tan growth which also appears to involve the serosa of the ovary. The fimbria of the Fallopian tube are adhered to the surface of the ovary. Also present in the container is a segment of Fallopian tube measuring 5 cm in length and ranging from 1.0 to 1.5 cm in diameter. There is a 1.5 cm cystically dilated region at the center of the tube which contains brown fluid. Labelled E1, cystically dilated area; E2, ovary; E3, tube/mesovarium. [REDACTED]

The sixth container is labelled "#6, right tube and ovary." It consists of an ovary that measures 4.3 x 1.5 x 1.1 cm which has a relatively smooth gray-white cortical surface. The Fallopian tube is adjacent to and adhered to the ovary, measures 7 cm in length x 0.5 cm in diameter, and contains, within the connective tissue, between the tube and ovary, a moderately firm yellow-white nodule.

There is also a piece of fat measuring 2.5 cm in greatest dimension adherent to the fimbriated end of the tube. Labelled F1, ovary; F2, tube, including adhesions. [REDACTED]

The seventh container is labelled "#7, sigmoid colon." It consists of a segment of intestine measuring 12 cm in length. The diameter of the fragment, including dense adjacent mesenteric fat, ranges from 4 to 7 cm. While the surrounding fat is focally hemorrhagic and indurated, the mucosa appears unremarkable, with no intraluminal lesions. Labelled G1, unremarkable bowel; G2, inflamed diverticulum. Jar 2. [REDACTED]

COMMENT

Microscopic examination substantiates the above cited diagnosis. [REDACTED]

{End of Report}

Source: NCI Genomic Data Commons file 476369ae-bf1d-4ce9-864b-462429e7e92b (TCGA-24-2260.920817F6-BD04-4E9A-8F41-BA28BE22CBC8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).